Gene-level copy-number profile of tumor specimen MP2PRT-PAPFBK-TMP1-A from MP2PRT case MP2PRT-PAPFBK, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.4 years (865 days).
Specimen MP2PRT-PAPFBK-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5322c842-50c2-4b3b-8a6b-b83589f84835.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PAPFBK-NM1-A (blood derived cancer - bone marrow, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/c44724ae-acd0-43de-bec6-40c0eac78d56

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 448; copy number 1: 4,618; copy number 2: 53,283; copy number 3: 535.

Homozygous deletions (total copy number 0; autosomes only): 447 genes in 24 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–632,616, 36 genes (within-gene range 0–2): DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2, FAM138A, OR4G4P, OR4G11P, OR4F5, AL627309.1, AL627309.3, CICP27, AL627309.6, AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2, AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6, AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2.
- chr2:88,811,186–89,254,015, 42 genes (within-gene range 0–2): MALLP2, AC244205.1, MIR4436A, IGKC, IGKJ5, IGKJ4, IGKJ3, IGKJ2, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV3-20, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30, IGKV3-31, IGKV1-32.
- chr3:128,572,000–128,576,086, 1 gene: LINC01565.
- chr4:83,003,412–83,003,517, 1 gene (within-gene range 0–2): RNU6-615P.
- chr5:134,601,149–134,649,271, 2 genes (within-gene range 0–2): SAR1B, RNU6-1311P.
- chr5:174,751,734–174,751,787, 1 gene (within-gene range 0–2): MIR4634.
- chr7:23,450,658–23,450,722, 1 gene (within-gene range 0–2): RNU7-143P.
- chr7:38,239,580–38,340,998, 17 genes (within-gene range 0–2): TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,350,022, 2 genes (within-gene range 0–2): TRGV5P, TRGV5.
- chr7:142,645,961–142,802,748, 27 genes: TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBC2.
- chr8:95,599,114–95,599,219, 1 gene (within-gene range 0–1): RNU6-690P.
- chr9:126,860,665–126,885,878, 1 gene: ZBTB34.
- chr11:8,169,167–8,178,903, 1 gene: RIC3-DT.
- chr11:135,061,781–135,075,908, 1 gene: LINC02684.
- chr12:133,217,210–133,238,549, 4 genes: AC226150.1, ANHX, RNU6-717P, Y_RNA.
- chr13:45,418,162–45,420,371, 1 gene (within-gene range 0–2): SLC25A30-AS1.
- chr13:114,306,646–114,337,626, 3 genes: CLCP2, CHAMP1, LINC01054.
- chr14:21,924,063–22,552,156, 110 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:105,672,308–106,675,544, 145 genes (within-gene range 0–2) (broad region; genes not listed).
- chr14:106,865,627–106,879,812, 4 genes: IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:101,887,354–101,979,093, 11 genes: WBP1LP5, AC140725.2, OR4F4, OR4G2P, OR4G6P, FAM138E, AC140725.1, MIR1302-10, WASH3P, MIR6859-3, DDX11L9.
- chr18:49,560,699–49,599,185, 1 gene: LIPG.
- chr19:19,740,884–19,754,986, 3 genes: AC011477.6, AC011477.7, AC011477.5.
- chr22:22,032,745–22,245,515, 31 genes (within-gene range 0–2): IGLVI-68, AC245452.4, AC245452.3, IGLV10-54, IGLV10-67, AC245452.2, IGLVIV-66-1, IGLVV-66, IGLVIV-65, IGLVIV-64, IGLVI-63, IGLV1-62, AC245517.5, IGLV8-61, AC245517.1, ABHD17AP5, AC245517.4, AC245517.3, IGLV4-60, AC245517.2, SOCS2P2, IGLVIV-59, IGLVV-58, BMP6P1, IGLV6-57, IGLVI-56, IGLV11-55, IGLVIV-53, TOP3BP1, AC245060.3, VPREB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,763. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
